Somatic mutation profile of tumor specimen TCGA-WB-A81N-01A (aliquot TCGA-WB-A81N-01A-11D-A35I-08) from TCGA case TCGA-WB-A81N, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 28.2 years (10,283 days).
Specimen TCGA-WB-A81N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bae2e15-a976-407e-ba30-6adeb77a48c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A81N-10A (Blood Derived Normal), aliquot TCGA-WB-A81N-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e859f6a-9b87-462b-a5d2-ea37e2a002d5

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Frame Shift Del 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSF2RA | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SLFN11 | c.811del p.R271Efs*4 | Frame Shift Del (DEL) | VAF 9/91 reads (10%) | called by mutect2, pindel*
- RFNG | c.654A>G p.P218= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs1163183951; called by muse, mutect2, varscan2
- TKTL1 | c.1641C>T p.C547= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as rs782124719; called by muse, mutect2, varscan2
